Somatic mutation profile of tumor specimen 0DTP4Y from CCDI case PBCJEM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Carcinoma, metastatic, NOS; Tissue or organ of origin: Thyroid gland; Age at diagnosis: 15.9 years (5,823 days).
Specimen 0DTP4Y: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2b736a5b-b24c-4231-a820-d431d2d7d3f1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DTP5C (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/539b6a3d-e601-4670-a7c6-2d679b9df0ab

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CSMD2 | c.3788C>T p.P1263L | Missense Mutation (SNP) | VAF 34/642 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.905); called by muse, mutect2
- NUP93 | c.107T>A p.I36N | Missense Mutation (SNP) | VAF 103/883 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- TNKS2 | c.3152T>C p.I1051T | Missense Mutation (SNP) | VAF 71/1332 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.742); called by muse, mutect2
- DKKL1 | c.*34C>T | 3'UTR (SNP) | VAF 18/216 reads (8%) | called by muse, mutect2
